Somatic mutation profile of tumor specimen TCGA-06-0216-01B (aliquot TCGA-06-0216-01B-01D-1492-08) from TCGA case TCGA-06-0216, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.7 years (22,524 days).
Specimen TCGA-06-0216-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f3d5a27-0863-4f48-9d40-30d4290dccba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0216-10A (Blood Derived Normal), aliquot TCGA-06-0216-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d10addf6-d7d0-479a-98c4-0f832fd8f3ab

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 38, Silent 19, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs148839428, COSV62322288; called by muse, mutect2, varscan2
- AGAP6 | c.770G>C p.R257T (on ENST00000374056 / NM_001365867.1; = p.R280T on NM_001077665.2) | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV65017537; called by muse, mutect2, varscan2
- AOC1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs767383158, COSV62867863; called by muse, mutect2, varscan2
- BNIP3 | c.312T>A p.Y104* | Nonsense Mutation (SNP) | VAF 66/118 reads (56%) | catalogued as COSV64043775; called by muse, mutect2, varscan2
- CAPN6 | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 122/340 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60693952; called by muse, mutect2, varscan2
- CENPS-CORT | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV57630472; called by muse, mutect2, varscan2
- CEP70 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53875009; called by muse, mutect2, varscan2
- COQ4 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs572683310, COSV55956722; called by muse, mutect2, varscan2
- CPA6 | c.535-1G>C p.X179_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV52725665; called by muse, varscan2
- CRACD | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (1); PolyPhen possibly damaging (0.536); catalogued as rs376583594; called by muse, mutect2, varscan2
- DAGLA | c.3026G>A p.S1009N | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV57195178; called by muse, mutect2, varscan2
- DIS3 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs1282336780, COSV58321928; called by muse, mutect2, varscan2
- DZIP3 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100848124, COSV64311651; called by muse, mutect2, varscan2
- EFNA5 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as COSV60946655; called by muse, mutect2, varscan2
- FNDC3B | c.3092A>G p.Q1031R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV61040030; called by muse, mutect2, varscan2
- GALNT9 | c.1184G>A p.R395H (on ENST00000328957 / NM_001122636.2; = p.R29H on NM_021808.3) | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs375596382; called by muse, mutect2, varscan2
- GIMAP6 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV100188367, COSV61032997; called by muse, mutect2, varscan2
- GPR50 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 186/607 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV54438108; called by muse, mutect2, varscan2
- HTR2A | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 147/442 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as COSV66327018; called by muse, mutect2, varscan2
- INPP5D | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748315737, COSV64035937; called by muse, mutect2, varscan2
- INTS6L | c.2377G>C p.G793R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66084087; called by muse, mutect2, varscan2
- KLHL15 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60139780; called by muse, mutect2
- LRRC3B | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV67520698; called by muse, mutect2, varscan2
- LRRC55 | c.588T>A p.N196K | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73006423; called by muse, mutect2, varscan2
- MARF1 | c.4927G>A p.V1643I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as rs946990272, COSV60019608; called by muse, mutect2, varscan2
- MRGPRX4 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1444628507, COSV58589735; called by muse, mutect2, varscan2
- MUC16 | c.15718A>G p.K5240E | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1209210318, COSV67457187; called by muse, mutect2, varscan2
- NLRP12 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as rs1325036444, COSV60745775; called by muse, mutect2
- NOP53 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as rs141718194; called by muse, mutect2, varscan2
- OR11L1 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 79/149 reads (53%) | catalogued as rs770557105, COSV63314047; called by muse, mutect2, varscan2
- PAPPA2 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.041); catalogued as COSV62775969; called by muse, mutect2, varscan2
- PTEN | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1111458, CM131884, COSV64291957, COSV64294035, COSV64296475; called by muse, mutect2, varscan2
- PTGS1 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543848883, COSV56291099; called by muse, mutect2, varscan2
- SH3TC1 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV55283054; called by muse, mutect2, varscan2
- SHB | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66628830; called by muse, mutect2, varscan2
- SLITRK2 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59424372; called by muse, mutect2, varscan2
- SMTNL2 | c.626G>A p.G209E (on ENST00000389313 / NM_001114974.2; = p.G65E on NM_198501.3) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV58807543; called by muse, mutect2
- SOX3 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV65168100, COSV65168386; called by muse, mutect2
- TBC1D9B | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV62281558; called by muse, mutect2, varscan2
- TCHH | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV64273949; called by muse, mutect2, varscan2
- TTN | c.17812A>T p.N5938Y (on ENST00000591111; = p.N5011Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/198 reads (36%) | PolyPhen benign (0); catalogued as COSV59976365; called by muse, mutect2, varscan2
- WFDC13 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV57913646; called by muse, mutect2, varscan2
- ZMYM3 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs372250348, COSV58736625; called by muse, mutect2, varscan2
- CD22 | c.1549dup p.S517Ffs*14 | Frame Shift Ins (INS) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- GPR85 | c.489_492del p.F165Lfs*20 | Frame Shift Del (DEL) | VAF 43/163 reads (26%) | called by mutect2, pindel, varscan2
- RPL5 | c.480dup p.G161Wfs*24 | Frame Shift Ins (INS) | VAF 64/157 reads (41%) | called by mutect2, pindel, varscan2
- AACS | c.1728C>T p.N576= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV55535772; called by muse, mutect2, varscan2
- BCAT1 | c.162G>A p.T54= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs372121259, COSV99678169; called by muse, mutect2, varscan2
- CD2 | c.915G>A p.Q305= | Silent (SNP) | VAF 80/178 reads (45%) | catalogued as COSV65643991, COSV65644062; called by muse, mutect2, varscan2
- CDH17 | c.255C>T p.D85= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV50327099; called by muse, mutect2
- CIT | c.5148C>T p.N1716= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs780981739, COSV55863415; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNGB1 | c.627C>T p.A209= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV51899403; called by muse, mutect2, varscan2
- DRD5 | c.1284C>T p.D428= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs201092734, COSV58576916; called by muse, mutect2, varscan2
- FGD1 | c.1029C>T p.D343= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs374074159, COSV64307974, COSV64308457; called by muse, mutect2, varscan2
- HAP1 | c.1242G>A p.S414= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs782606075, COSV100169802, COSV57878057; called by muse, mutect2, varscan2
- HIPK1 | c.3276G>T p.S1092= (on ENST00000369558 / NM_001369806.1; = p.S698= on NM_181358.2) | Silent (SNP) | VAF 90/220 reads (41%) | catalogued as rs780166628, COSV61245721, COSV61247036; called by muse, mutect2, varscan2
- IMPG2 | c.3174T>C p.P1058= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV51976115; called by muse, mutect2, varscan2
- IZUMO1R | c.720G>A p.P240= (on ENST00000440961; = p.P247= on NM_001199206.3) | Silent (SNP) | VAF 153/311 reads (49%) | catalogued as rs376599967; called by muse, mutect2, varscan2
- KHDRBS2 | c.717A>T p.A239= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV55441410; called by muse, mutect2, varscan2
- LRRC4C | c.651G>A p.P217= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs370666599, COSV53439640; called by muse, mutect2, varscan2
- NUMA1 | c.5502G>A p.S1834= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs763350835, COSV52620379; called by muse, mutect2, varscan2
- OTUD4 | c.660G>A p.V220= (on ENST00000447906 / NM_001366057.1; = p.V155= on NM_001102653.1) | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV56850334; called by muse, mutect2, varscan2
- PPP4R3B | c.2241G>A p.K747= (on ENST00000616407 / NM_001122964.3; = p.K662= on NM_020463.4) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV55403387; called by muse, mutect2, varscan2
- RSPO1 | c.102C>T p.A34= | Silent (SNP) | VAF 65/150 reads (43%) | catalogued as rs746161623, COSV62973808; called by muse, mutect2, varscan2
- VPS35 | c.2349A>C p.S783= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV54477942; called by muse, mutect2, varscan2
